Gene-level copy-number profile of specimen HCM-SANG-1094-C16-85A-01D-A80T-32 from HCMI case HCM-SANG-1094-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-1094-C16-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 03cdf3e4-e3aa-4822-b998-6979675bb823.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1094-C16-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/386e01fe-c36a-48d4-9e2c-0d1f3f392a92

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 475; copy number 1: 10; copy number 2: 722; copy number 3: 1,111; copy number 4: 24,626; copy number 5: 7,218; copy number 6: 16,629; copy number 7: 2,472; copy number 8: 2,501; copy number 9: 945; copy number 10: 1,004; copy number 11: 530; copy number 12: 444; copy number 13: 81; copy number 14: 27; copy number 15: 9; copy number 16: 2; copy number 25: 9; copy number 26: 29; copy number 27: 8; copy number 32: 3; copy number 33: 4; copy number 34: 5; copy number 35: 8; copy number 37: 33; copy number 39: 2.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,218,853–204,377,665, 4 genes (within-gene range 0–4): PLEKHA6, AL592114.3, AL592114.1, LINC00628.
- chr1:210,303,684–211,207,138, 13 genes (within-gene range 0–4): AL035414.1, HHAT, AL034351.4, RNU5A-8P, AL034351.3, BPNT2P, KCNH1, AC096636.1, AL590132.1, IPO8P1, AC092017.2, AC092017.3, KCNH1-IT1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,143 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene, copy number 9: CFHR3.
- chr2:181,076,051–191,820,257, 126 genes, copy number 10–13 (within-gene range 6–13) (broad region; genes not listed).
- chr2:193,730,555–215,848,954, 368 genes, copy number 10 (broad region; genes not listed).
- chr3:159,902,045–161,821,908, 33 genes, copy number 9: IL12A-AS1, IL12A, LINC01100, BRD7P2, C3orf80, AC079594.1, IFT80, RPL35AP10, SMC4, MIR15B, MIR16-2, TRIM59, B3GAT3P1, RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC131211.1.
- chr3:169,709,295–171,054,973, 46 genes, copy number 11–13: SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2.
- chr3:197,960,200–198,123,232, 9 genes, copy number 10: LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr8:57,855,500–76,867,281, 279 genes, copy number 9–11 (broad region; genes not listed).
- chr8:77,399,072–137,698,467, 822 genes, copy number 9–12 (broad region; genes not listed).
- chr11:112,787,304–132,336,822, 474 genes, copy number 9–10 (within-gene range 7–10) (broad region; genes not listed).
- chr14:80,954,989–82,796,221, 27 genes, copy number 10 (within-gene range 4–10): TSHR, BHLHB9P1, RPL17P3, AC007262.1, AC007262.2, NMNAT1P1, AL136040.2, GTF2A1, SNORA79, AL136040.1, DYNLL1P1, UNGP3, STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311, AL355838.1, RPL9P6, EIF3LP1, Metazoa_SRP, LINC02301, ENSAP2, AL355095.1.
- chr14:83,903,437–85,654,428, 14 genes, copy number 11: LINC02305, MTND4P33, MTND5P35, MTCYBP27, RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2.
- chr14:86,905,778–97,688,600, 215 genes, copy number 10–16 (broad region; genes not listed).
- chr15:35,919,892–36,887,035, 14 genes, copy number 9–10: LINC02853, MIR4510, AC021351.1, AC087516.1, AC087516.2, COX6CP4, CDIN1, AC103988.1, LARP4P, TPST2P1, AC013640.1, CSNK1A1P1, U3, AC018563.1.
- chr15:42,273,233–45,513,767, 130 genes, copy number 9–14 (within-gene range 4–14) (broad region; genes not listed).
- chr15:56,542,952–56,918,571, 5 genes, copy number 13 (within-gene range 4–13): AC090518.1, ZNF280D, Y_RNA, AC090517.4, AC090517.2.
- chr15:56,795,460–56,918,499, 1 gene, copy number 13 (within-gene range 4–13): AC090517.5.
- chr15:57,591,904–57,782,762, 4 genes, copy number 10–11: MYZAP, GCOM1, POLR2M, AC090651.1.
- chr15:58,410,569–58,569,844, 5 genes, copy number 12 (within-gene range 4–12): LIPC, LIPC-AS1, AC084781.1, AC084781.2, AC018904.2.
- chr15:66,278,498–66,550,130, 20 genes, copy number 9–10 (within-gene range 7–10): AC055855.2, DIS3L, AC055855.1, TIPIN, SCARNA14, Y_RNA, RPL9P25, MAP2K1, ATP5MFP6, RPL35AP32, AC116913.1, SNAPC5, MIR4512, RPL4, SNORD18C, AC116913.2, SNORD18B, SNORD16, SNORD18A, ZWILCH.
- chr15:67,200,667–69,843,120, 52 genes, copy number 9–11: AAGAB, RPS24P16, IQCH, IQCH-AS1, C15orf61, AC016355.1, MAP2K5, HNRNPA1P5, SKOR1, AC009292.2, AC009292.1, RNU6-1, AC022254.1, AC135628.1, PIAS1, AC107871.1, CALML4, CLN6, HMGN2P40, AC107871.2, FEM1B, ITGA11, CORO2B, CARS1P1, ANP32A, MIR4312, SPESP1, AC087639.1, AC087639.2, AC027088.1, NOX5, AC027088.5, AC027088.4, AC027088.3, EWSAT1, AC027088.2, GLCE, AC026992.2, AC026992.1, PAQR5, AC027237.4, AC027237.3, Y_RNA, KIF23, AC027237.1, RPLP1, U3, AC027237.2, DRAIC, AC100826.1, GEMIN8P1, AC021818.1.
- chr15:76,215,353–77,820,900, 29 genes, copy number 10 (within-gene range 4–10): ETFA, Metazoa_SRP, TYRO3P, AC027243.3, ISL2, AC027243.1, AC027243.2, SCAPER, AC090751.1, MIR3713, RN7SKP217, RCN2, RN7SL278P, KRT8P23, PSTPIP1, TSPAN3, AC090181.1, AC090181.3, AC090181.2, PEAK1, AC087465.1, AC060773.1, HMG20A, AC090984.1, AC046168.1, AC046168.2, LINGO1, LINGO1-AS1, LINGO1-AS2.
- chr15:89,504,909–90,275,778, 42 genes, copy number 9–15 (within-gene range 4–15): LINC00928, AC013391.3, AC013391.2, TICRR, AC013391.1, KIF7, PLIN1, PEX11A, RPL36AP43, WDR93, AC079075.1, RNU6-132P, MESP1, MRPL15P1, MESP2, ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN.
- chr15:90,275,129–90,275,716, 1 gene, copy number 9 (within-gene range 4–9): AC091167.1.
- chr15:101,289,784–101,525,202, 1 gene, copy number 12 (within-gene range 4–14): PCSK6.
- chr15:101,334,437–101,337,428, 1 gene, copy number 12 (within-gene range 12–14): PCSK6-AS1.
- chr18:21,825,487–21,831,539, 3 genes, copy number 10 (within-gene range 8–10): MIR133A1HG, MIR133A1, MIR1-2.
- chr18:21,871,446–23,026,488, 21 genes, copy number 10 (within-gene range 7–10): AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8.
- chr18:24,932,771–25,352,190, 7 genes, copy number 9–10: LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1.
- chr18:58,862,600–59,697,662, 13 genes, copy number 10–26 (within-gene range 2–26): ZNF532, RNU2-69P, OACYLP, AC040963.1, SEC11C, GRP, RAX, CPLX4, LMAN1, AC016229.2, CCBE1, AC016229.1, AC090213.1.
- chr18:62,650,308–62,650,601, 1 gene, copy number 33: RN7SL705P.
- chr18:74,597,870–80,247,514, 104 genes, copy number 9–39 (within-gene range 6–39) (broad region; genes not listed).
- chr20:43,189,998–50,756,795, 235 genes, copy number 9 (broad region; genes not listed).
- chr22:20,495,913–21,070,097, 32 genes, copy number 12–13: MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP.
- chr22:37,550,026–37,582,616, 4 genes, copy number 10: AL022315.1, CDC42EP1, LGALS2, Metazoa_SRP.
- chr22:45,502,238–45,680,130, 4 genes, copy number 9–13 (within-gene range 5–13): FBLN1, LINC01589, RNU6-1161P, Z95331.1.

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
